Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-4684, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-4684-01A (Primary Tumor).

FINAL DIAGNOSIS:

TCGA-AZ-4684

PARTS 1

AND 2: RECTOSIGMOID COLON, ANASTOMOTIC RINGS, LAPAROSCOPIC COLECTOMY AND ANASTOMOSIS -

- A. FUNGATING, NON-CIRCUMFERENTIAL, INVASIVE, MODERATELY TO POORLY-DIFFERENTIATED COLORECTAL ADENOCARCINOMA, 5.5 CM IN GREATEST DIAMETER. CARCINOMA STRADDLES THE RECTOSIGMOID JUNCTION WITH INVASION THROUGH MUSCULARIS PROPRIA AND FOCAL EXTENSION INTO PERICOLORECTAL ADIPOSE TISSUE.
- B. PRESUMED ANGIOLYMPHATIC INVASION (See diagnosis D).
- C. ALL SURGICAL RESECTION MARGINS ARE BENIGN. CARCINOMA IS 0.5 CM FROM THE CLOSEST (circumferential) RESECTION MARGIN (Slide 1I).
- D. METASTATIC COLORECTAL ADENOCARCINOMA IS PRESENT IN TEN OF TWELVE (10/12) REGIONAL LYMPH NODES. THE LARGEST METASTATIC FOCUS MEASURES 1 CM IN GREATEST DIAMETER (Slide 1U). NO EXTRACAPSULAR EXTENSION IS IDENTIFIED (see comment).
- E. TWO SMALL HYPERPLASTIC POLYPS (Slides 1O and 1P).
- F. NON-NEOPLASTIC COLORECTAL MUCOSA WITH NO SIGNIFICANT HISTOPATHOLOGIC ABNORMALITY.
- G. TNM PATHOLOGIC STAGE: pT3, N2, Mx (see Synoptic).

PART 3: APPENDIX, APPENDECTOMY -

- A. APPENDIX WITHOUT HISTOPATHOLOGIC ABNORMALITY.
- B. NO EVIDENCE OF MALIGNANCY.

PART 4: RIGHT DOME OF LIVER, LIVER BIOPSY -

METASTATIC COLONIC ADENOCARCINOMA IN LIVER (Slides 4A and 4B).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY COLON, RECTAL, APPENDIX TUMORS

SPECIMEN TYPE: Rectal/rectosigmoid colon (low anterior resection)

SPECIMEN LENGTH: 23.5 cm

TUMOR SITE: Rectosigmoid

TUMOR CONFIGURATION: Exophytic (polypoid)

TUMOR SIZE: Greatest dimension: 5.5 cm

Additional dimensions: 3.5 cm

INTACTNESS OF MESORECTUM: Complete

HISTOLOGIC TYPE: Adenocarcinoma

HISTOLOGIC GRADE: Other: Moderate to poorly differentiated

PATHOLOGIC STAGING (pTNM): pT3a/b

pN2

Number of nodes examined: 12

Number of nodes involved: 10

pM1

Site(s): Liver

MARGINS:

Proximal margin uninvolved by invasive carcinoma

Distal margin uninvolved by invasive carcinoma

Circumferential (radial) margin uninvolved by invasive carcinoma

Mesenteric margin uninvolved by invasive carcinoma

ANGIOLYMPHATIC INVASION:

Present

PERINEURAL INVASION:

Absent

TUMOR BORDER CONFIGURATION: Infiltrating

TUMORAL LYMPHOCYTIC RESPONSE: Mild to moderate

ADDITIONAL PATHOLOGIC FINDINGS: Other polyps (type[s]): Two hyperplastic polyps

Source: NCI Genomic Data Commons file 9141f237-1671-4b17-ab8e-5f18049c4ed3 (TCGA-AZ-4684.3E3C0AA0-73DD-47F1-989B-2871336385AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).